Somatic mutation profile of tumor specimen TARGET-10-PAPILF-09A (aliquot TARGET-10-PAPILF-09A-01D) from TARGET case TARGET-10-PAPILF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,657 days).
Specimen TARGET-10-PAPILF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7f707df-90b2-4d87-b085-c527c89f605a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPILF-10A (Blood Derived Normal), aliquot TARGET-10-PAPILF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de8a732e-f72b-45dd-a975-092407efa621

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, Silent 2, RNA 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 27/54 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.3134G>A p.R1045Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs754731736, COSV60092080, COSV60099133; called by muse, mutect2, varscan2
- EMC1 | c.2353G>A p.V785M | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs770588339, COSV64345819; called by muse, mutect2, varscan2
- NCBP2 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.35); catalogued as COSV58317775; called by muse, mutect2, varscan2
- CACNA2D1 | c.2252A>T p.N751I (on ENST00000356253 / NM_001366867.1; = p.N739I on NM_000722.4) | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF713 | c.98G>T p.W33L (on ENST00000633730 / NM_001366796.2; = p.W46L on NM_182633.3) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARMC3 | c.2022C>T p.S674= | Silent (SNP) | VAF 60/190 reads (32%) | catalogued as rs374503216; called by muse, mutect2, varscan2
- RUNX1T1 | c.864C>A p.G288= (on ENST00000265814 / NM_001198628.1; = p.G261= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- CRMP1 | chr4:5889754 C>T | 5'Flank (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- GGTA1 | c.116+58C>A | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- LXN | c.-69G>T | 5'UTR (SNP) | VAF 10/30 reads (33%) | catalogued as rs527321098, COSV99962953; called by muse, varscan2
- MUCL3 | c.947-443C>T | Intron (SNP) | VAF 13/410 reads (3%) | catalogued as rs1236872993; called by muse, mutect2
- OR2L1P | n.575C>G | RNA (SNP) | VAF 68/232 reads (29%) | called by muse, mutect2, varscan2
